Somatic mutation profile of tumor specimen TCGA-37-4135-01A (aliquot TCGA-37-4135-01A-01D-1352-08) from TCGA case TCGA-37-4135, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.6 years (25,041 days).
Specimen TCGA-37-4135-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4667af78-9ccb-48cc-b4d1-0c1389a20801.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-4135-10A (Blood Derived Normal), aliquot TCGA-37-4135-10A-01D-1352-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca81d4b9-e4d0-470d-8f10-81f8f454506d

The open-access MAF lists 322 somatic variants for this specimen: 235 protein-altering or splice-affecting, 75 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 207, Silent 75, Nonsense Mutation 13, Frame Shift Del 8, Intron 5, Splice Site 3, Frame Shift Ins 3, 3'Flank 3, 3'UTR 2, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4416G>T p.W1472C | Missense Mutation (SNP) | VAF 156/358 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52117493; called by mutect2, varscan2
- NFE2L2 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101229454, COSV67961584, COSV67961602; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 243/285 reads (85%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD3 | c.608A>T p.H203L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV56677196; called by muse, mutect2, varscan2
- ADAM12 | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 265/318 reads (83%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV64109012, COSV64109701; called by muse, mutect2, varscan2
- ADAM19 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446761254, COSV57433585; called by muse, mutect2, varscan2
- AGBL4 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65740152, COSV65746681; called by muse, mutect2, varscan2
- ANKRD44 | c.320G>T p.W107L | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV56559020; called by muse, mutect2, varscan2
- APOBEC2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 18/358 reads (5%) | catalogued as COSV55143013; called by muse, mutect2
- ASIC4 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.607); catalogued as COSV61732445; called by muse, mutect2
- ATP13A1 | c.2235G>A p.M745I | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV52288342; called by muse, mutect2, varscan2
- ATP2B1 | c.1723G>C p.V575L | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53809798; called by muse, mutect2, varscan2
- AUH | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 77/91 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV57864394; called by muse, mutect2, varscan2
- B3GLCT | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 143/168 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375168040, COSV58456500; called by muse, mutect2, varscan2
- BAHCC1 | c.7718C>T p.A2573V | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs781918039, COSV57025971; called by muse, mutect2
- BICRAL | c.1985G>C p.G662A | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV58406899; called by muse, mutect2, varscan2
- BMS1 | c.533A>T p.K178I | Missense Mutation (SNP) | VAF 166/211 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65734516; called by muse, mutect2, varscan2
- BOLA3 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54877087; called by muse, mutect2, varscan2
- BUB1B | c.1852G>C p.V618L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV55014283; called by muse, varscan2
- CAD | c.6305G>T p.R2102L | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV53028813; called by muse, mutect2, varscan2
- CALN1 | c.308C>A p.P103H (on ENST00000329008 / NM_001017440.3; = p.P145H on NM_031468.4) | Missense Mutation (SNP) | VAF 217/314 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61132203; called by muse, mutect2, varscan2
- CAPN1 | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 63/76 reads (83%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as rs1382095822, COSV54199864; called by muse, mutect2, varscan2
- CASZ1 | c.2064C>G p.H688Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59738184; called by muse, mutect2, varscan2
- CDH11 | c.944C>A p.S315* | Nonsense Mutation (SNP) | VAF 374/852 reads (44%) | catalogued as COSV51768263, COSV99218747; called by muse, mutect2, varscan2
- CDH18 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 162/340 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56937437; called by muse, mutect2, varscan2
- CEP85 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 128/444 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53330738; called by mutect2, varscan2
- CFLAR | c.1171G>T p.G391W | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as COSV58580900; called by muse, mutect2, varscan2
- CHEK1 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54022963, COSV54023166; called by muse, mutect2, varscan2
- CHRM2 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57777075; called by muse, mutect2, varscan2
- CHST9 | c.1183T>C p.F395L | Missense Mutation (SNP) | VAF 62/502 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52442235; called by muse, mutect2, varscan2
- CLDN11 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 182/769 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs549752354, COSV50355194; called by muse, mutect2, varscan2
- CLSPN | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 136/486 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52053461; called by muse, mutect2, varscan2
- CNGB3 | c.2237C>A p.P746Q | Missense Mutation (SNP) | VAF 124/167 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV60692836; called by muse, varscan2
- CNKSR2 | c.2307G>C p.Q769H | Missense Mutation (SNP) | VAF 209/228 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV54260563, COSV99669225; called by muse, mutect2, varscan2
- COL1A2 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 279/424 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV51961103; called by muse, mutect2, varscan2
- CRCP | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 116/534 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV58536083; called by muse, mutect2, varscan2
- CTPS2 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 243/262 reads (93%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63723220; called by muse, mutect2, varscan2
- CYBB | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM001659, COSV66085806; called by muse, mutect2, varscan2
- DDX10 | c.2209A>G p.K737E | Missense Mutation (SNP) | VAF 565/587 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59436878; called by muse, mutect2, varscan2
- DGKK | c.2346A>T p.Q782H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65708340; called by muse, mutect2
- DIS3L | c.623A>T p.Q208L (on ENST00000319212 / NM_001143688.3; = p.Q125L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 252/449 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59913209; called by muse, mutect2, varscan2
- DSG1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770676155, COSV57137079; called by muse, mutect2, varscan2
- EDIL3 | c.952+1G>A p.X318_splice | Splice Site (SNP) | VAF 66/77 reads (86%) | catalogued as rs746089721, COSV56906784; called by muse, mutect2, varscan2
- EFCAB7 | c.1350G>C p.E450D | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV64314951; called by muse, mutect2, varscan2
- EPHA4 | c.2294T>C p.F765S | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56037626; called by muse, mutect2, varscan2
- ERICH3 | c.3807G>T p.R1269S | Missense Mutation (SNP) | VAF 225/431 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.037); catalogued as COSV58611468; called by muse, mutect2, varscan2
- EXOC6B | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 100/293 reads (34%) | catalogued as COSV55561717; called by muse, varscan2
- EXTL1 | c.1451C>A p.P484Q | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV65332964; called by muse, mutect2, varscan2
- EZH1 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 207/451 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV70550013; called by muse, mutect2, varscan2
- F13A1 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 215/388 reads (55%) | catalogued as COSV53561814; called by muse, mutect2, varscan2
- F13B | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1359475077, COSV66374632; called by muse, mutect2, varscan2
- FAM53C | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 142/173 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as COSV53512242; called by muse, mutect2, varscan2
- FAM83C | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65583637; called by muse, mutect2, varscan2
- FDX2 | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV58533438; called by muse, mutect2, varscan2
- FKBP7 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 184/349 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV51846883; called by muse, mutect2, varscan2
- FLRT3 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 141/349 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV54010890; called by muse, mutect2, varscan2
- FNDC3B | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV61045283; called by muse, mutect2, varscan2
- FOXC2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV57444778; called by muse, mutect2, varscan2
- GABPB1 | c.1080A>C p.E360D | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55016103; called by muse, mutect2
- GABRA3 | c.814A>C p.K272Q | Missense Mutation (SNP) | VAF 165/185 reads (89%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); catalogued as COSV64801521; called by muse, mutect2, varscan2
- GFI1 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs781101695, COSV54043168; called by muse, mutect2, varscan2
- GFRAL | c.1027G>T p.G343* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV61232681; called by muse, mutect2, varscan2
- GJA9 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 182/570 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62532430; called by muse, mutect2, varscan2
- GP9 | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56624420; called by muse, varscan2
- GPR158 | c.2185A>G p.K729E | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66274959; called by muse, mutect2, varscan2
- GRB14 | c.909C>G p.N303K | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV55739969; called by muse, mutect2, varscan2
- GUF1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as COSV55783543; called by muse, mutect2, varscan2
- HCAR3 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63675644, COSV63678365; called by muse, mutect2, varscan2
- HCN4 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56085080; called by muse, mutect2, varscan2
- HNRNPA1 | c.216G>C p.M72I | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV52937381, COSV52937625; called by muse, mutect2, varscan2
- HOXD3 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50882204; called by muse, mutect2, varscan2
- HR | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV57193240; called by muse, varscan2
- HSPA4 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59182886; called by muse, mutect2, varscan2
- HYAL1 | c.860T>A p.V287D | Missense Mutation (SNP) | VAF 77/92 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV56498555; called by muse, mutect2, varscan2
- ICE1 | c.4134G>T p.M1378I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56828252; called by muse, mutect2, varscan2
- ICE1 | c.4135G>C p.E1379Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV56828258; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 1120/1948 reads (57%) | catalogued as rs752639270; called by muse, mutect2, varscan2
- IL16 | c.3950G>A p.R1317K (on ENST00000302987 / NM_172217.5; = p.R616K on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV57155373; called by muse, mutect2, varscan2
- ILVBL | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 112/195 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54620824; called by muse, mutect2, varscan2
- ING1 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58170423; called by muse, mutect2, varscan2
- INSYN1 | c.244T>A p.S82T | Missense Mutation (SNP) | VAF 158/605 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV65837565; called by muse, mutect2, varscan2
- IQCE | c.540G>T p.R180S | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58079767; called by muse, mutect2, varscan2
- ITGB6 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 274/471 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1014857218, COSV51796102; called by muse, mutect2, varscan2
- ITPRIPL1 | c.706G>C p.D236H (on ENST00000439118 / NM_001008949.3; = p.D244H on NM_178495.6) | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV63154000; called by muse, mutect2, varscan2
- KCNC2 | c.1138A>T p.N380Y | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54372589; called by muse, mutect2, varscan2
- KCNE3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs542842233, COSV59552185; called by muse, mutect2, varscan2
- KCNH6 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100120939, COSV59005076; called by muse, mutect2, varscan2
- KCNK17 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 85/400 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs142227833, COSV64686024; called by muse, mutect2, varscan2
- KCNN1 | c.1214T>C p.I405T | Missense Mutation (SNP) | VAF 182/212 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV55840092; called by muse, mutect2, varscan2
- KCNQ4 | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 143/289 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61273987; called by muse, mutect2, varscan2
- KCNT2 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 123/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54081501, COSV54090551; called by muse, mutect2, varscan2
- KIAA1109 | c.13402G>T p.G4468* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as COSV52681323; called by muse, mutect2, varscan2
- KMT2D | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56459136, COSV99986332; called by muse, mutect2, varscan2
- LAMP3 | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 183/522 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs113287351, COSV55615648; called by muse, mutect2, varscan2
- LCLAT1 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs758773276, COSV58374969, COSV58379073; called by muse, mutect2, varscan2
- LILRB2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 243/289 reads (84%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as rs372550280; called by muse, mutect2, varscan2
- LIMCH1 | c.948A>T p.R316S | Missense Mutation (SNP) | VAF 108/148 reads (73%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as COSV58288744; called by muse, mutect2, varscan2
- LRP1B | c.13454G>T p.G4485V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67245095; called by muse, mutect2, varscan2
- LRP3 | c.2263T>G p.C755G | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53505370; called by muse, mutect2, varscan2
- LRRC30 | c.716T>A p.L239H | Missense Mutation (SNP) | VAF 121/142 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV67301953; called by muse, mutect2, varscan2
- LRRC74A | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.36); catalogued as COSV53610760; called by muse, mutect2, varscan2
- LRRK2 | c.5683C>G p.R1895G | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as CM125636, COSV54159784; called by muse, mutect2, varscan2
- LRRN2 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.783); catalogued as COSV65784229; called by muse, mutect2, varscan2
- LRSAM1 | c.1745C>A p.S582* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as COSV55939727, COSV55941054; called by muse, mutect2, varscan2
- MAGEA11 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 312/328 reads (95%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60756054; called by muse, mutect2, varscan2
- MED1 | c.4222G>A p.V1408M | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs771425321, COSV56126684; called by muse, mutect2, varscan2
- MED12 | c.1639G>C p.A547P | Missense Mutation (SNP) | VAF 65/69 reads (94%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.677); catalogued as COSV61336964, COSV61345889; called by muse, mutect2, varscan2
- MMP26 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV56172721, COSV56172868; called by muse, mutect2, varscan2
- MON1B | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1233560788, COSV50249098; called by muse, mutect2, varscan2
- MRPL47 | c.496G>C p.G166R | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52023416; called by muse, mutect2, varscan2
- MRTFA | c.1640C>T p.T547M | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs780407081, COSV62934588; called by muse, mutect2
- MTCL1 | c.4366G>A p.E1456K (on ENST00000306329 / NM_001378206.1; = p.E1137K on NM_015210.4) | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as rs752584375, COSV60408312; called by muse, mutect2, varscan2
- MTOR | c.2095G>C p.A699P | Missense Mutation (SNP) | VAF 101/170 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63874202; called by muse, mutect2, varscan2
- MUC16 | c.38741C>A p.P12914H | Missense Mutation (SNP) | VAF 164/196 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV67477695; called by muse, mutect2, varscan2
- MUC17 | c.11605A>T p.T3869S | Missense Mutation (SNP) | VAF 80/415 reads (19%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.518); catalogued as COSV60294431; called by muse, mutect2, varscan2
- MYO9A | c.5782C>A p.L1928I | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61853705; called by muse, mutect2, varscan2
- MYOM1 | c.4522G>T p.G1508W | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55295243; called by muse, mutect2, varscan2
- MYOM3 | c.4090C>A p.P1364T | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58396481; called by muse, mutect2, varscan2
- MYRF | c.1955C>G p.T652S (on ENST00000278836 / NM_001127392.3; = p.T643S on NM_013279.4) | Missense Mutation (SNP) | VAF 174/215 reads (81%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53890793; called by muse, mutect2, varscan2
- NAV2 | c.5383C>T p.R1795C (on ENST00000396087 / NM_001244963.2; = p.R1739C on NM_145117.5) | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs755116010, COSV60661450; called by muse, mutect2, varscan2
- NAV3 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.951); catalogued as rs1254657390, COSV57093047; called by muse, mutect2, varscan2
- NR5A2 | c.823G>A p.D275N (on ENST00000367362 / NM_205860.3; = p.D229N on NM_003822.5) | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV52653229; called by muse, mutect2, varscan2
- NSUN2 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 384/854 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV52955493; called by muse, varscan2
- NUP98 | c.947T>C p.M316T | Missense Mutation (SNP) | VAF 292/336 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV61434663; called by muse, mutect2, varscan2
- OBSCN | c.11678G>T p.R3893L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as COSV52746847, COSV99476656; called by muse, mutect2, varscan2
- OCA2 | c.1647C>A p.H549Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as CM990982, COSV62350701; called by muse, mutect2, varscan2
- OPLAH | c.2890G>A p.V964M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782716446, COSV70678568; called by muse, mutect2, varscan2
- OR10AD1 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59612764; called by muse, mutect2, varscan2
- OR11L1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63314916, COSV63315252; called by muse, varscan2
- OR11L1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 176/310 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs768876019, COSV100869464, COSV63314922; called by muse, varscan2
- OR2A14 | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 519/772 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV68718386; called by muse, mutect2, varscan2
- OR2G6 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 149/246 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58575059; called by muse, mutect2, varscan2
- OR2M5 | c.156C>G p.D52E | Missense Mutation (SNP) | VAF 500/1574 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.144); catalogued as COSV63546372, COSV63546617; called by muse, varscan2
- OR2T33 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 157/518 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs763304871, COSV100531814; called by muse, mutect2, varscan2
- OR4C15 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 193/228 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV58953941; called by muse, mutect2, varscan2
- OR4S1 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs373016390; called by muse, mutect2, varscan2
- OR51L1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 295/349 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1370241599, COSV58625173; called by muse, mutect2, varscan2
- OR52A5 | c.651A>G p.I217M | Missense Mutation (SNP) | VAF 164/182 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56615836; called by muse, mutect2, varscan2
- OR5B12 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 137/222 reads (62%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100222527, COSV56905752; called by muse, mutect2, varscan2
- OR5M1 | c.131G>T p.C44F | Missense Mutation (SNP) | VAF 172/206 reads (83%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV73202244; called by muse, varscan2
- OR8B3 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63541916; called by muse, mutect2, varscan2
- OVGP1 | c.1468G>T p.G490* | Nonsense Mutation (SNP) | VAF 62/193 reads (32%) | catalogued as COSV63858990; called by muse, mutect2, varscan2
- PAQR5 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs371623789; called by muse, mutect2, varscan2
- PARP6 | c.1835A>G p.D612G | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV53003928; called by muse, mutect2, varscan2
- PCDHGA2 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 186/216 reads (86%) | catalogued as COSV53930831, COSV99527854; called by mutect2, varscan2
- PCSK2 | c.497T>C p.M166T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52737029; called by muse, mutect2, varscan2
- PDIA2 | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV51989366; called by muse, mutect2
- PEX2 | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 187/214 reads (87%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.498); catalogued as COSV63813868; called by muse, mutect2, varscan2
- PHF11 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 67/77 reads (87%) | SIFT tolerated (0.22); PolyPhen benign (0.11); catalogued as COSV62896733; called by muse, mutect2, varscan2
- PIK3C2B | c.3325G>T p.G1109W | Missense Mutation (SNP) | VAF 171/313 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65812796; called by muse, mutect2, varscan2
- PIWIL1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 89/148 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs370704151; called by muse, mutect2, varscan2
- PKD2 | c.2563A>G p.S855G | Missense Mutation (SNP) | VAF 74/96 reads (77%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.952); catalogued as rs373306069; called by muse, mutect2, varscan2
- PLA1A | c.155A>C p.Q52P | Missense Mutation (SNP) | VAF 146/895 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs769137788, COSV56332583; called by muse, mutect2, varscan2
- PLEKHA1 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 73/91 reads (80%) | catalogued as rs1273800006, COSV64569764; called by muse, mutect2, varscan2
- PLEKHG4B | c.3539A>T p.H1180L (on ENST00000283426; = p.H1536L on NM_052909.5) | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV52050442; called by muse, mutect2, varscan2
- PLEKHG7 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as rs761184263, COSV67338019; called by muse, mutect2, varscan2
- PLXNA4 | c.4880A>T p.Y1627F | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.909); catalogued as COSV58140509; called by muse, mutect2, varscan2
- PRCC | c.991G>T p.G331W | Missense Mutation (SNP) | VAF 539/1045 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54857226; called by muse, mutect2, varscan2
- PRDM5 | c.1411G>T p.V471F | Missense Mutation (SNP) | VAF 120/154 reads (78%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53363169; called by muse, mutect2, varscan2
- PRICKLE1 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.638); catalogued as rs776819993, COSV58207362; called by muse, mutect2, varscan2
- PRKAA2 | c.1445G>C p.G482A | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV64804769; called by muse, mutect2, varscan2
- PRPS2 | c.405G>A p.Q135= | Splice Region (SNP) | VAF 84/177 reads (47%) | catalogued as COSV101028349, COSV66126430; called by muse, mutect2, varscan2
- PTPRB | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV51737770; called by muse, mutect2, varscan2
- RADIL | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68202148; called by muse, mutect2, varscan2
- RASGRP3 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV67823120; called by muse, mutect2, varscan2
- RCOR3 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV65366179; called by muse, mutect2, varscan2
- RELN | c.2651G>C p.G884A | Missense Mutation (SNP) | VAF 237/360 reads (66%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV58987402, COSV59015023; called by muse, mutect2, varscan2
- RIMBP2 | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.855); catalogued as COSV55477408, COSV55480323; called by muse, mutect2, varscan2
- RIT2 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56303223; called by muse, mutect2, varscan2
- RNF213 | c.11231A>C p.Q3744P | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV60402145; called by muse, mutect2, varscan2
- SALL1 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV51760523; called by muse, mutect2, varscan2
- SBSN | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV71733294; called by muse, mutect2, varscan2
- SERPINB11 | c.335C>A p.T112K | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV66957326; called by muse, mutect2, varscan2
- SETD5 | c.4271A>T p.Q1424L | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV56713939; called by muse, mutect2, varscan2
- SIGLEC14 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV55781221; called by muse, mutect2, varscan2
- SLC1A3 | c.1343T>A p.L448Q | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54318070; called by muse, mutect2, varscan2
- SLC4A10 | c.2015C>G p.P672R (on ENST00000446997 / NM_001354461.2; = p.P642R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55787130; called by muse, mutect2, varscan2
- SLC6A18 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV57252552; called by muse, mutect2, varscan2
- SLK | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 126/135 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59826790; called by muse, mutect2, varscan2
- SPACA3 | c.572T>A p.L191Q | Missense Mutation (SNP) | VAF 230/471 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1388438453, COSV52191746; called by muse, mutect2, varscan2
- SPAG17 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1271324411, COSV60456696, COSV60462464; called by muse, mutect2, varscan2
- SPATA16 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 294/1407 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV63530912; called by muse, mutect2, varscan2
- SPHKAP | c.2085C>G p.N695K | Missense Mutation (SNP) | VAF 379/637 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs770515231, COSV100763715, COSV60885204; called by muse, mutect2, varscan2
- SPRY3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 140/160 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV57143567; called by muse, mutect2, varscan2
- STXBP5 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 175/294 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV51654739; called by muse, mutect2, varscan2
- STYK1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 174/200 reads (87%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV104380316, COSV50013921; called by muse, mutect2, varscan2
- SUPT6H | c.2230-1G>T p.X744_splice | Splice Site (SNP) | VAF 89/220 reads (40%) | catalogued as COSV58928983; called by muse, mutect2, varscan2
- TBL3 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV60342164; called by muse, mutect2, varscan2
- TBR1 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 65/239 reads (27%) | catalogued as rs771354583, COSV67418327; called by muse, mutect2, varscan2
- TBX22 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs758506603, COSV64786818; called by muse, mutect2, varscan2
- TBX22 | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 133/142 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV64786829, COSV64787013; called by muse, mutect2, varscan2
- TDRKH | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 225/425 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64316512; called by muse, mutect2, varscan2
- TIA1 | c.731G>A p.R244Q (on ENST00000433529 / NM_001351511.1; = p.R233Q on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777224522, COSV57007266; called by muse, mutect2, varscan2
- TIE1 | c.2485C>A p.L829M | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV65250288; called by muse, mutect2, varscan2
- TIMELESS | c.3586A>C p.K1196Q | Missense Mutation (SNP) | VAF 191/329 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV57513044; called by muse, mutect2, varscan2
- TINAG | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1299797191, COSV52511768; called by muse, mutect2, varscan2
- TMEM132B | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 162/639 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54759134; called by muse, mutect2, varscan2
- TOGARAM2 | c.1845_1846insC p.G616Rfs*15 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | catalogued as COSV101091057; called by mutect2, pindel, varscan2
- TRIM26 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370667148; called by muse, mutect2, varscan2
- TRIM42 | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53884572; called by muse, mutect2, varscan2
- TRPC5 | c.2118C>A p.S706R | Missense Mutation (SNP) | VAF 151/175 reads (86%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53295841; called by muse, mutect2, varscan2
- TTK | c.1697A>G p.D566G | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV57884909; called by muse, mutect2, varscan2
- TUBGCP2 | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53306684; called by muse, mutect2, varscan2
- UBQLN3 | c.1638G>A p.M546I | Missense Mutation (SNP) | VAF 82/99 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1326958665, COSV61164722; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3456G>T p.R1152S | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54439421; called by muse, mutect2, varscan2
- ULBP1 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 214/587 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57664569; called by muse, mutect2, varscan2
- USH2A | c.14119G>C p.E4707Q | Missense Mutation (SNP) | VAF 120/653 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV56394785; called by muse, mutect2, varscan2
- VILL | c.1617C>G p.F539L | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52186134; called by muse, mutect2, varscan2
- VSTM1 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 187/236 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58075624; called by muse, mutect2, varscan2
- XIRP2 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.007); catalogued as COSV54713581; called by muse, mutect2, varscan2
- ZFHX4 | c.4565C>A p.P1522H | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756374230, COSV51463500; called by muse, mutect2, varscan2
- ZFP36L2 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1326635637, COSV56699103; called by muse, varscan2
- ZNF235 | c.1112G>C p.G371A | Missense Mutation (SNP) | VAF 87/96 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52155739; called by muse, mutect2, varscan2
- ZNF277 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV100702395; called by muse, mutect2, varscan2
- ZNF341 | c.1102C>G p.H368D (on ENST00000375200 / NM_001282935.1; = p.H361D on NM_032819.4) | Missense Mutation (SNP) | VAF 136/574 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61009834; called by muse, mutect2, varscan2
- ZNF521 | c.3768C>A p.F1256L | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100831685, COSV64128904; called by muse, mutect2, varscan2
- ZNF91 | c.3317A>G p.Y1106C | Missense Mutation (SNP) | VAF 115/138 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766600532, COSV56087618; called by muse, mutect2, varscan2
- ZNRF2 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV59911500; called by muse, mutect2, varscan2
- ZRANB3 | c.1820G>T p.S607I | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV51507062; called by muse, mutect2, varscan2
- ZSCAN5B | c.1063T>C p.F355L | Missense Mutation (SNP) | VAF 141/163 reads (87%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV62000554; called by muse, mutect2, varscan2
- BAZ1B | c.2330_2331insT p.W777Cfs*13 | Frame Shift Ins (INS) | VAF 42/288 reads (15%) | called by pindel, varscan2
- CLCNKB | c.500del p.X167_splice | Splice Site (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- CNGB3 | c.2299_2314del p.P767Gfs*57 | Frame Shift Del (DEL) | VAF 108/176 reads (61%) | called by pindel, varscan2
- CTNND2 | c.1195_1198del p.Y399Afs*21 | Frame Shift Del (DEL) | VAF 49/166 reads (30%) | called by mutect2, pindel, varscan2
- DNAJC1 | c.1083_1085delinsGTT p.R362L | Missense Mutation (TNP) | VAF 6/43 reads (14%) | called by muse*, pindel, varscan2*
- EYA1 | c.593del p.G198Efs*43 | Frame Shift Del (DEL) | VAF 98/166 reads (59%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.844del p.D282Ifs*20 | Frame Shift Del (DEL) | VAF 222/356 reads (62%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by mutect2, varscan2
- GNPDA2 | c.94del p.D32Tfs*15 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- KAZALD1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by mutect2, varscan2
- MLLT6 | c.1328_1335del p.K443Tfs*11 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel
- OR5M3 | c.724del p.H242Ifs*2 | Frame Shift Del (DEL) | VAF 86/114 reads (75%) | called by mutect2, varscan2
- PLCB3 | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPS6KC1 | c.261dup p.G88Wfs*4 | Frame Shift Ins (INS) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- ZFP14 | c.933del p.Y312Mfs*68 | Frame Shift Del (DEL) | VAF 153/241 reads (63%) | called by mutect2, pindel, varscan2
- ACACA | c.2973G>C p.R991= | Silent (SNP) | VAF 144/334 reads (43%) | catalogued as rs1472017176; called by muse, mutect2, varscan2
- ADAMTS16 | c.3369G>A p.A1123= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs200762006, COSV56989092; called by muse, mutect2, varscan2
- AMELY | c.201T>C p.Y67= (on ENST00000383036 / NM_001364814.1; = p.Y53= on NM_001143.1) | Silent (SNP) | VAF 189/202 reads (94%) | catalogued as COSV53095936; called by muse, mutect2, varscan2
- AP2M1 | c.753T>C p.C251= | Silent (SNP) | VAF 28/454 reads (6%) | catalogued as rs1560127152, COSV53048983; called by muse, mutect2
- ARHGEF10L | c.2010G>T p.T670= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV51435694; called by muse, mutect2, varscan2
- BCAP31 | c.258C>T p.P86= | Silent (SNP) | VAF 212/230 reads (92%) | catalogued as rs782421344, COSV61452015; called by muse, mutect2, varscan2
- C5orf34 | c.417T>C p.S139= | Silent (SNP) | VAF 77/342 reads (23%) | catalogued as COSV60930967; called by muse, mutect2, varscan2
- CCDC102B | c.1368A>T p.A456= | Silent (SNP) | VAF 96/176 reads (55%) | catalogued as COSV60146661; called by muse, mutect2, varscan2
- CCR1 | c.891C>T p.N297= | Silent (SNP) | VAF 67/84 reads (80%) | catalogued as COSV56122556; called by muse, mutect2, varscan2
- CDH6 | c.2196C>T p.Y732= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs1213304652, COSV54068459; called by muse, mutect2, varscan2
- CHD6 | c.4932A>G p.T1644= | Silent (SNP) | VAF 91/136 reads (67%) | catalogued as rs780349103, COSV64692383; called by muse, mutect2, varscan2
- CHMP6 | c.585G>T p.A195= | Silent (SNP) | VAF 123/276 reads (45%) | catalogued as COSV57327657; called by muse, mutect2, varscan2
- CHST1 | c.822G>T p.T274= | Silent (SNP) | VAF 138/159 reads (87%) | catalogued as COSV57324395; called by muse, mutect2, varscan2
- CNR1 | c.1161G>A p.L387= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as COSV62989100; called by muse, mutect2, varscan2
- CNST | c.669G>A p.L223= | Silent (SNP) | VAF 103/205 reads (50%) | catalogued as COSV63620716; called by muse, mutect2, varscan2
- DCTN6 | c.529C>T p.L177= | Silent (SNP) | VAF 74/105 reads (70%) | catalogued as COSV55318037; called by muse, mutect2, varscan2
- DMRT3 | c.489G>C p.S163= | Silent (SNP) | VAF 143/162 reads (88%) | catalogued as COSV51901955, COSV51906193; called by muse, mutect2, varscan2
- DZIP1L | c.576G>A p.V192= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV59522098; called by muse, varscan2
- ENOX2 | c.888C>G p.A296= (on ENST00000338144 / NM_001382520.1; = p.A267= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 156/368 reads (42%) | catalogued as COSV57654279; called by muse, mutect2, varscan2
- EPHA1 | c.783G>A p.R261= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV51972847; called by muse, mutect2, varscan2
- EPPK1 | c.6336G>A p.V2112= | Silent (SNP) | VAF 180/644 reads (28%) | catalogued as COSV73261802; called by muse, mutect2, varscan2
- FAM43A | c.1152C>A p.G384= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1036362849, COSV61673266; called by muse, mutect2, varscan2
- FAT1 | c.2439C>T p.V813= | Silent (SNP) | VAF 127/321 reads (40%) | catalogued as rs776073338, COSV71671980; called by muse, mutect2, varscan2
- FBN1 | c.2256A>G p.S752= | Silent (SNP) | VAF 158/276 reads (57%) | catalogued as COSV57322430; called by muse, mutect2, varscan2
- FCGBP | c.5496A>T p.T1832= | Silent (SNP) | VAF 99/211 reads (47%) | called by muse, mutect2, varscan2
- FCRL3 | c.1788C>T p.Y596= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as rs566843294, COSV63843110; called by muse, mutect2, varscan2
- FCSK | c.1242C>A p.G414= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV55372751; called by muse, mutect2, varscan2
- FPGT | c.966A>G p.G322= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as COSV63842733; called by muse, mutect2, varscan2
- FRMPD2 | c.645G>A p.G215= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs374495446; called by muse, mutect2, varscan2
- FUBP3 | c.1377G>T p.G459= | Silent (SNP) | VAF 109/131 reads (83%) | catalogued as rs774986512, COSV60515069; called by muse, mutect2, varscan2
- GIMAP4 | c.192C>T p.S64= | Silent (SNP) | VAF 33/45 reads (73%) | catalogued as COSV55433514, COSV99751017; called by muse, mutect2, varscan2
- GPR148 | c.894A>G p.T298= | Silent (SNP) | VAF 62/260 reads (24%) | catalogued as COSV59308735; called by muse, mutect2, varscan2
- GPR31 | c.543C>G p.L181= | Silent (SNP) | VAF 340/738 reads (46%) | catalogued as COSV64761744; called by muse, mutect2, varscan2
- H3C11 | c.156C>T p.I52= | Silent (SNP) | VAF 35/190 reads (18%) | catalogued as COSV58900610; called by muse, varscan2
- HBA1 | c.360T>C p.P120= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV52265809; called by muse, mutect2, varscan2
- HTATSF1 | c.1800C>T p.S600= | Silent (SNP) | VAF 95/203 reads (47%) | catalogued as rs750556357, COSV54479787; called by muse, mutect2, varscan2
- IGFN1 | c.3165G>T p.G1055= (on ENST00000295591 / NM_001367841.1; = p.G3512= on NM_001164586.2) | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV55175234, COSV55177047; called by muse, mutect2, varscan2
- IGKV1D-43 | c.258C>A p.G86= | Silent (SNP) | VAF 143/176 reads (81%) | called by muse, mutect2, varscan2
- IQCH | c.1527A>G p.K509= | Silent (SNP) | VAF 174/295 reads (59%) | catalogued as COSV60055899; called by muse, mutect2, varscan2
- IRAG1 | c.1899G>A p.T633= | Silent (SNP) | VAF 219/575 reads (38%) | catalogued as rs755592463, COSV70211948; called by muse, varscan2
- ITPRIPL1 | c.855G>C p.L285= (on ENST00000439118 / NM_001008949.3; = p.L293= on NM_178495.6) | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV63154007; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1062G>T p.L354= (on ENST00000439118 / NM_001008949.3; = p.L362= on NM_178495.6) | Silent (SNP) | VAF 55/558 reads (10%) | catalogued as COSV63154012; called by muse, mutect2, varscan2
- KIAA1549 | c.5670G>A p.E1890= (on ENST00000422774 / NM_001164665.2; = p.E1874= on NM_020910.3) | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV54319652; called by muse, mutect2, varscan2
- KLHL5 | c.51A>G p.A17= | Silent (SNP) | VAF 119/156 reads (76%) | catalogued as COSV54676083; called by muse, mutect2, varscan2
- LAMA5 | c.7170G>T p.R2390= | Silent (SNP) | VAF 106/193 reads (55%) | catalogued as COSV53364264; called by muse, varscan2
- LMTK3 | c.2862A>G p.R954= | Silent (SNP) | VAF 156/182 reads (86%) | catalogued as COSV54314236; called by muse, mutect2, varscan2
- LRRC4C | c.1206G>T p.R402= | Silent (SNP) | VAF 347/407 reads (85%) | catalogued as COSV53430841; called by muse, mutect2, varscan2
- LTN1 | c.580C>T p.L194= | Silent (SNP) | VAF 58/85 reads (68%) | catalogued as COSV63734360; called by muse, mutect2, varscan2
- LYST | c.2895T>A p.S965= | Silent (SNP) | VAF 226/432 reads (52%) | catalogued as rs745971703, COSV67709612; called by muse, mutect2, varscan2
- MAP2K1 | c.219G>A p.E73= | Silent (SNP) | VAF 364/639 reads (57%) | catalogued as COSV61071974; called by muse, mutect2, varscan2
- MDN1 | c.4527G>A p.L1509= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as COSV65517310; called by muse, mutect2, varscan2
- ME3 | c.561T>C p.D187= | Silent (SNP) | VAF 136/242 reads (56%) | catalogued as rs1300785434, COSV60165364; called by muse, mutect2, varscan2
- MROH2B | c.3444G>T p.V1148= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV68186304; called by muse, mutect2, varscan2
- MYCBP2 | c.5433A>T p.T1811= (on ENST00000357337; = p.T1849= on NM_015057.5) | Silent (SNP) | VAF 174/194 reads (90%) | catalogued as COSV100630289, COSV62027644; called by muse, mutect2, varscan2
- MYH1 | c.4578C>A p.R1526= | Silent (SNP) | VAF 83/96 reads (86%) | catalogued as COSV56852006, COSV99876943; called by muse, mutect2, varscan2
- NDST2 | c.930C>T p.D310= | Silent (SNP) | VAF 103/124 reads (83%) | catalogued as COSV55216099; called by muse, mutect2, varscan2
- OR2G3 | c.415C>A p.R139= | Silent (SNP) | VAF 240/675 reads (36%) | catalogued as COSV60682346, COSV60682414; called by muse, mutect2, varscan2
- OR2T4 | c.378C>T p.A126= | Silent (SNP) | VAF 441/795 reads (55%) | catalogued as COSV63544490; called by muse, mutect2, varscan2
- OTOGL | c.1986G>T p.V662= (on ENST00000547103; = p.V653= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as COSV101509170, COSV72007351; called by muse, mutect2, varscan2
- PACRG | c.468C>T p.A156= | Silent (SNP) | VAF 283/606 reads (47%) | catalogued as rs375336076; called by muse, mutect2, varscan2
- PARP15 | c.1809C>A p.T603= (on ENST00000464300 / NM_001113523.3; = p.T369= on NM_152615.2) | Silent (SNP) | VAF 166/452 reads (37%) | catalogued as COSV59973468; called by muse, mutect2, varscan2
- PSG9 | c.603C>G p.T201= | Silent (SNP) | VAF 503/602 reads (84%) | catalogued as COSV52486233, COSV99392018; called by muse, mutect2, varscan2
- RDH8 | c.895C>A p.R299= (on ENST00000651512; = p.R279= on NM_015725.4) | Silent (SNP) | VAF 79/94 reads (84%) | catalogued as rs759794792, COSV50675926, COSV99408827; called by muse, mutect2, varscan2
- RSAD2 | c.1077G>C p.L359= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as COSV65908565; called by muse, mutect2, varscan2
- RYR2 | c.2988G>A p.V996= | Silent (SNP) | VAF 80/131 reads (61%) | catalogued as COSV63696180; called by muse, mutect2, varscan2
- SLC2A2 | c.12T>C p.D4= | Silent (SNP) | VAF 405/893 reads (45%) | catalogued as COSV58586930; called by muse, mutect2, varscan2
- SLC8A1 | c.648C>A p.T216= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as COSV60487268; called by muse, mutect2, varscan2
- TARS2 | c.1842C>T p.F614= | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as COSV60873830; called by muse, mutect2, varscan2
- TBXT | c.357G>A p.A119= | Silent (SNP) | VAF 63/278 reads (23%) | catalogued as COSV51618882; called by muse, mutect2, varscan2
- TEKT4 | c.807G>A p.L269= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs111598357, COSV54626288, COSV99726838; called by muse, mutect2, varscan2
- VIP | c.261C>A p.T87= | Silent (SNP) | VAF 103/317 reads (32%) | catalogued as COSV65889276, COSV65889391; called by muse, mutect2, varscan2
- VRTN | c.1335G>T p.R445= | Silent (SNP) | VAF 73/97 reads (75%) | catalogued as COSV56442101; called by muse, mutect2, varscan2
- ZBTB24 | c.1179A>G p.L393= | Silent (SNP) | VAF 101/414 reads (24%) | catalogued as rs926989674, COSV57782594; called by muse, mutect2, varscan2
- ZNF37A | c.228G>A p.Q76= | Silent (SNP) | VAF 43/52 reads (83%) | catalogued as rs766936428, COSV100697329, COSV61074330; called by muse, mutect2, varscan2
- ZNF557 | c.426A>G p.A142= (on ENST00000414706 / NM_001044388.2; = p.A149= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/135 reads (79%) | catalogued as rs370454440, COSV53274513; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+157C>G | Intron (SNP) | VAF 148/708 reads (21%) | catalogued as COSV99180703; called by muse, mutect2, varscan2
- DOCK4 | c.2736+3923C>T | Intron (SNP) | VAF 69/112 reads (62%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178055683 G>A | 3'Flank (SNP) | VAF 23/113 reads (20%) | catalogued as rs765601243; called by muse, mutect2, varscan2
- FAM153CP | chr5:178056003 G>A | 3'Flank (SNP) | VAF 28/160 reads (18%) | catalogued as rs755183862; called by muse, varscan2
- GLRX5 | chr14:95533401 A>C | 5'Flank (SNP) | VAF 30/480 reads (6%) | called by muse, mutect2
- MSTN | c.*1G>C | 3'UTR (SNP) | VAF 77/128 reads (60%) | catalogued as COSV99640642, COSV99640731; called by muse, mutect2, varscan2
- NACA | c.71-2351G>T | Intron (SNP) | VAF 45/177 reads (25%) | catalogued as COSV100771252; called by muse, mutect2, varscan2
- OBSCN | c.18662-2932G>T | Intron (SNP) | VAF 13/29 reads (45%) | catalogued as rs546316599, COSV99476659; called by muse, varscan2
- OSBPL6 | c.987+4562G>T | Intron (SNP) | VAF 84/159 reads (53%) | catalogued as COSV99507207; called by muse, mutect2, varscan2
- PAOX | c.*44G>T | 3'UTR (SNP) | VAF 40/49 reads (82%) | catalogued as COSV99529779; called by muse, mutect2
- SAMD3 | c.-2C>A | 5'UTR (SNP) | VAF 57/255 reads (22%) | catalogued as rs760444215, COSV100148211; called by muse, mutect2, varscan2
- SPAG11A | chr8:7863512 C>T | 3'Flank (SNP) | VAF 23/196 reads (12%) | catalogued as rs780498174, COSV58500723; called by mutect2, varscan2
